Gene-level copy-number profile of tumor specimen HTMCP-03-06-02180-01A from CGCI case HTMCP-03-06-02180, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02180-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e05cb0b1-3d3b-47d0-b513-aeeba47b313d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02180-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b8748318-10d7-49e6-b2ed-2dd2c65fb1e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 11,841; copy number 2: 42,019; copy number 3: 4,420; copy number 4: 58; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,231,417–248,655,528, 25 genes: OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27.
- chr1:248,681,322–248,716,755, 2 genes (within-gene range 0–1): OR14I1, LYPD9P.
- chr4:1,210,120–1,218,591, 1 gene (within-gene range 0–1): CTBP1-AS.
- chr4:9,459,255–9,460,244, 1 gene: OR7E86P.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:119,405,523–119,454,638, 3 genes: GTF2IP12, AC093752.3, RNU6-1217P.
- chr4:119,456,350–119,457,277, 1 gene (within-gene range 0–1): AC093752.2.
- chr9:102,055,252–102,055,741, 1 gene: ARL2BPP7.
- chr11:112,967–186,136, 5 genes (within-gene range 0–1): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr13:46,455,131–46,515,958, 3 genes (within-gene range 0–1): LINC01198, AL138686.2, OR7E101P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes, copy number 5: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.

Autosomal genes at a single copy (total copy number 1): 11,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
